Somatic mutation profile of tumor specimen TCGA-BA-5152-01A (aliquot TCGA-BA-5152-01A-02D-1870-08) from TCGA case TCGA-BA-5152, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.9 years (20,783 days).
Specimen TCGA-BA-5152-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81c9b748-a6c4-48bd-be72-e10351ebcdc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-5152-10A (Blood Derived Normal), aliquot TCGA-BA-5152-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6287240-b6b5-41a9-b12f-6dd4eb9b835f

The open-access MAF lists 536 somatic variants for this specimen: 384 protein-altering or splice-affecting, 140 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 335, Silent 140, Nonsense Mutation 33, Splice Site 6, RNA 5, Splice Region 5, Intron 4, Nonstop Mutation 2, 5'UTR 2, Frame Shift Ins 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 32/66 reads (48%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 45/117 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.684C>G p.F228L | Missense Mutation (SNP) | VAF 113/309 reads (37%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV100879511; called by muse, mutect2, varscan2
- ABR | c.1440C>G p.F480L (on ENST00000302538 / NM_021962.5; = p.F443L on NM_001092.5) | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV99348690; called by muse, mutect2, varscan2
- ACACB | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as COSV100623325; called by muse, mutect2
- ACSM2A | c.1073G>A p.R358Q (on ENST00000219054; = p.R279Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs188648395, COSV54581766, COSV99525176; called by muse, mutect2, varscan2
- ADAM15 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs773958488, COSV55060488; called by muse, mutect2, varscan2
- ADAMTS3 | c.3085C>T p.Q1029* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as COSV99712179; called by muse, mutect2, varscan2
- ADAMTS8 | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs775007123, COSV99961613; called by muse, mutect2, varscan2
- ADGRF1 | c.1761G>T p.W587C | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1464597161, COSV99347657; called by muse, varscan2
- ADGRF1 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs112946460, COSV99347662; called by muse, mutect2, varscan2
- ADGRF1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99347675; called by muse, varscan2
- ADGRF5 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.08); catalogued as COSV99346508; called by muse, mutect2, varscan2
- ADRB1 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65167625; called by muse, mutect2, varscan2
- AGO3 | c.2163G>C p.R721S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV99869480; called by muse, mutect2, varscan2
- AGRP | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs975628688, COSV52097512; called by muse, mutect2, varscan2
- AHDC1 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.327); catalogued as rs1195926361, COSV99899786, COSV99899841; called by muse, mutect2, varscan2
- AHNAK | c.15022G>C p.E5008Q | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99945285, COSV99949612, COSV99949835; called by muse, mutect2, varscan2
- ALDH1L2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99311362; called by muse, mutect2, varscan2
- ALKBH4 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 15/103 reads (15%) | catalogued as rs1302020983, COSV99479586; called by muse, mutect2, varscan2
- ANKS1A | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.33); catalogued as COSV100832904; called by muse, mutect2, varscan2
- ANO5 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100202273; called by muse, mutect2, varscan2
- AP5Z1 | c.2321T>A p.V774E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100804258; called by muse, mutect2, varscan2
- APOB | c.12181G>A p.E4061K | Missense Mutation (SNP) | VAF 118/449 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs1414968929, CD920828, COSV51929766, COSV99268382; called by muse, mutect2, varscan2
- ARFGEF1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV99145040; called by muse, mutect2, varscan2
- ARFGEF1 | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV99145043; called by muse, mutect2
- ARHGAP26 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV99191538; called by muse, mutect2, varscan2
- ARHGEF10L | c.3340G>A p.G1114R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99393928; called by muse, mutect2, varscan2
- ARHGEF17 | c.4891G>A p.E1631K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV99736922; called by muse, mutect2, varscan2
- ARPP21 | c.1580C>A p.S527Y | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.406); catalogued as COSV99493519; called by muse, mutect2, varscan2
- ASMTL | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs771748500, COSV99060215; called by muse, mutect2
- ASPHD2 | c.229C>G p.H77D | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); catalogued as COSV99313633; called by muse, mutect2, varscan2
- ATG2A | c.3359C>T p.S1120F | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65968458; called by muse, mutect2
- ATRN | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 24/134 reads (18%) | catalogued as COSV99497896; called by muse, mutect2, varscan2
- ATXN7 | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 79/299 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99895429; called by muse, mutect2, varscan2
- BAD | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs1401297919, COSV54193098; called by muse, varscan2
- BDH1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs541287538, COSV64019031; called by muse, varscan2
- BIN2 | c.1221C>G p.I407M | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.054); catalogued as COSV99909757; called by muse, mutect2, varscan2
- BIRC3 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99680252; called by muse, mutect2, varscan2
- BNC1 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100597469, COSV100597516; called by muse, mutect2, varscan2
- BRAF | c.1945C>G p.Q649E (on ENST00000288602 / NM_001374244.1; = p.Q609E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV56391154, COSV99970169; called by muse, mutect2, varscan2
- BRD8 | c.2212G>A p.D738N (on ENST00000254900 / NM_139199.2; = p.D811N on NM_006696.4) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.751); catalogued as COSV99137732; called by muse, varscan2
- BSDC1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100345101; called by muse, mutect2, varscan2
- C12orf43 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 57/164 reads (35%) | catalogued as rs1412951851, COSV99990096; called by muse, mutect2, varscan2
- C12orf45 | c.552G>C p.K184N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV99774063; called by muse, mutect2, varscan2
- C17orf75 | c.675G>C p.L225F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56752747; called by muse, mutect2, varscan2
- C17orf75 | c.564G>C p.E188D | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as COSV99858808; called by muse, varscan2
- C22orf23 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV50777821, COSV99970222; called by muse, mutect2, varscan2
- C3orf20 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV99514206, COSV99514310; called by muse, mutect2, varscan2
- C5orf51 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV67565424; called by muse, mutect2, varscan2
- C8G | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.665); catalogued as rs753450750, COSV56403041; called by muse, mutect2, varscan2
- CACNB2 | c.1356C>G p.H452Q (on ENST00000324631 / NM_201596.3; = p.H397Q on NM_000724.4) | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99996600; called by muse, mutect2, varscan2
- CADPS2 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100466195; called by muse, mutect2, varscan2
- CAPS2 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100158344; called by muse, mutect2, varscan2
- CASP5 | c.788T>A p.V263E | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99508142; called by muse, mutect2, varscan2
- CCDC57 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs752746987, COSV100492691; called by muse, mutect2, varscan2
- CDKL4 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.348); catalogued as COSV101115558; called by muse, mutect2, varscan2
- CELF6 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99764229; called by muse, mutect2, varscan2
- CEP350 | c.9205G>C p.E3069Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100855318; called by muse, mutect2, varscan2
- CETN3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99300658; called by muse, mutect2, varscan2
- CFAP36 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.302); catalogued as COSV100171176; called by muse, mutect2
- CFLAR | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as COSV58581941; called by muse, mutect2, varscan2
- CHPF | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV99705347; called by muse, mutect2, varscan2
- CHRNA7 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100181806; called by mutect2, varscan2
- CLEC4F | c.834G>T p.L278F | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99714045; called by muse, mutect2, varscan2
- CNTRL | c.5221G>C p.E1741Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99444022; called by muse, mutect2, varscan2
- COL14A1 | c.368del p.R123Kfs*25 | Frame Shift Del (DEL) | VAF 58/182 reads (32%) | catalogued as COSV52865193; called by mutect2, pindel, varscan2
- COL15A1 | c.1024G>C p.G342R | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100898030; called by muse, mutect2, varscan2
- COL5A3 | c.3391C>A p.Q1131K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.834); catalogued as COSV53405409; called by muse, mutect2, varscan2
- COLQ | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV67524395; called by muse, mutect2, varscan2
- COPB1 | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV51448444, COSV99999953; called by muse, mutect2, varscan2
- COQ10A | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.243); catalogued as COSV100370060; called by muse, mutect2, varscan2
- CPB2 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.927); catalogued as COSV99473311; called by muse, mutect2, varscan2
- CRISP3 | c.632G>A p.R211K (on ENST00000371159 / NM_001368123.1; = p.R193K on NM_006061.4) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.035); catalogued as rs560259322, COSV99539329; called by muse, mutect2, varscan2
- CSMD1 | c.9205G>T p.V3069F (on ENST00000520002; = p.V3068F on NM_033225.6) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.11); catalogued as COSV100154243; called by muse, mutect2, varscan2
- CUBN | c.7153C>T p.Q2385* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | catalogued as COSV100913635; called by muse, mutect2, varscan2
- CUL2 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV101039316; called by muse, mutect2, varscan2
- CUL5 | c.2312C>G p.S771C | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV101263759; called by muse, mutect2, varscan2
- CXADR | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99515704; called by muse, mutect2, varscan2
- CYP11B2 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as COSV100011433, COSV59996680; called by muse, mutect2, varscan2
- CYP1A2 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV100673945; called by muse, mutect2, varscan2
- CYP1A2 | c.1254-1G>C p.X418_splice | Splice Site (SNP) | VAF 20/143 reads (14%) | catalogued as COSV100673946; called by muse, mutect2, varscan2
- CYP4X1 | c.1287G>C p.L429F | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.593); catalogued as COSV100903378; called by muse, mutect2, varscan2
- DDX20 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100865970; called by muse, mutect2, varscan2
- DENND1C | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as rs934262031, COSV100375450; called by muse, mutect2, varscan2
- DEPDC4 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100147437; called by muse, varscan2
- DEPDC4 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV100147438; called by muse, varscan2
- DGAT2L6 | c.922C>G p.H308D | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs996967355, COSV100284165, COSV60718210; called by muse, mutect2, varscan2
- DGCR8 | c.1545C>G p.I515M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100708183; called by muse, varscan2
- DIP2C | c.1278G>C p.Q426H | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV99793902; called by muse, mutect2, varscan2
- DIRAS1 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV60215061; called by muse, mutect2, varscan2
- DLGAP3 | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1217266034, COSV99029982; called by muse, mutect2, varscan2
- DMC1 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99319504; called by muse, mutect2, varscan2
- DNAH11 | c.5015C>T p.S1672F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100181117; called by muse, mutect2, varscan2
- DNAJC1 | c.605C>G p.S202* | Nonsense Mutation (SNP) | VAF 40/181 reads (22%) | catalogued as COSV100978054; called by muse, mutect2, varscan2
- DNM3 | c.1987C>T p.R663C (on ENST00000355305 / NM_001350206.2; = p.R657C on NM_015569.5) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs756468578, COSV62453812; called by muse, mutect2, varscan2
- DYNC1I1 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV100269392, COSV61460925; called by muse, mutect2
- EBF2 | c.1612C>G p.Q538E | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.321); catalogued as COSV101282291; called by muse, mutect2, varscan2
- EBF3 | c.1346C>T p.S449L (on ENST00000355311 / NM_001375392.1; = p.S440L on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV100799659; called by muse, mutect2, varscan2
- EGFL8 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs17853434, COSV100247121; called by muse, mutect2, varscan2
- EIF2AK4 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV99775433; called by muse, mutect2, varscan2
- EIF3G | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99460664, COSV99461893; called by muse, mutect2, varscan2
- ELOC | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV99514127; called by muse, mutect2, varscan2
- EMD | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.278); catalogued as rs782066603, COSV100877426; called by muse, mutect2, varscan2
- ENPEP | c.2413G>C p.E805Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as COSV54452626, COSV99488199; called by muse, mutect2, varscan2
- EPHA2 | c.1430G>C p.G477A | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV100626319; called by muse, mutect2, varscan2
- EPHA2 | c.1256C>G p.S419* | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | catalogued as COSV100626261; called by muse, mutect2, varscan2
- EPHA2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765981383, COSV100626040, COSV64453977; called by muse, mutect2, varscan2
- EPHA5 | c.2411G>A p.R804K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99901584; called by muse, mutect2, varscan2
- ESRP1 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100619691; called by muse, mutect2, varscan2
- ESRRA | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV99134794; called by muse, mutect2, varscan2
- ETAA1 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390210433, COSV55475565; called by muse, mutect2, varscan2
- EVX2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs1559103766, COSV100420853; called by muse, mutect2
- FAM104A | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as rs1165311175, COSV99278562; called by muse, mutect2
- FAM160B2 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.082); catalogued as rs1489511041; called by mutect2, varscan2
- FAN1 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62950351; called by muse, mutect2, varscan2
- FASN | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754942049, COSV60756291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBH1 | c.923C>T p.P308L (on ENST00000362091 / NM_178150.3; = p.P359L on NM_032807.4) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100758963; called by muse, mutect2, varscan2
- FBXO11 | c.633G>A p.M211I (on ENST00000403359 / NM_001190274.2; = p.M127I on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100320053; called by muse, mutect2, varscan2
- FDPS | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100756246, COSV100756305; called by muse, mutect2, varscan2
- FER1L5 | c.4131G>C p.K1377N (on ENST00000623019; = p.K1350N on NM_001293083.2) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV101208919; called by muse, mutect2, varscan2
- FER1L6 | c.2911G>C p.E971Q | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV101206220; called by muse, mutect2, varscan2
- FERMT3 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99656865; called by muse, mutect2, varscan2
- FKBP15 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs375150301; called by muse, mutect2
- FLG | c.4844C>T p.S1615F | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100912304; called by muse, mutect2, varscan2
- FOXP2 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV100647451; called by muse, mutect2, varscan2
- FREM2 | c.8388G>C p.W2796C | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99751221; called by muse, mutect2, varscan2
- FSCB | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV100469953; called by muse, mutect2
- G3BP1 | c.140C>G p.S47* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100664058; called by muse, mutect2, varscan2
- GABBR2 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); catalogued as rs1455549519, COSV52296619; called by muse, mutect2, varscan2
- GALNT12 | c.1479G>C p.Q493H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100899213; called by muse, mutect2, varscan2
- GANC | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 24/109 reads (22%) | PolyPhen benign (0.082); catalogued as COSV100531293; called by muse, mutect2, varscan2
- GCFC2 | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.294); catalogued as COSV100319747; called by muse, mutect2, varscan2
- GCNT4 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474294869, COSV100466634; called by muse, mutect2, varscan2
- GNB1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV101060870; called by muse, mutect2
- GPATCH11 | c.412C>T p.H138Y (on ENST00000409774; = p.H116Y on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as rs1340300156, COSV99931032; called by muse, mutect2, varscan2
- GSG1 | c.343G>A p.E115K (on ENST00000651961 / NM_001080555.4; = p.E102K on NM_031289.5) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100189572; called by muse, mutect2, varscan2
- H3C13 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100516165, COSV58943895, COSV58944644; called by muse, mutect2, varscan2
- HAT1 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51361812, COSV99908143; called by muse, mutect2
- HECA | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.555); catalogued as rs762507172, COSV62769392; called by muse, mutect2, varscan2
- HELZ2 | c.143C>G p.T48S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV100915726; called by muse, mutect2, varscan2
- HGF | c.1889G>C p.R630P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV55958353, COSV99738678; called by muse, mutect2, varscan2
- HLA-A | c.223T>C p.W75R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100954699; called by muse, mutect2, varscan2
- HNRNPA1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV99267911; called by muse, mutect2, varscan2
- ICAM1 | c.1425C>T p.L475= | Splice Region (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99321179; called by muse, mutect2, varscan2
- IFI16 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 12/280 reads (4%) | catalogued as rs1386919621; called by muse, mutect2
- IGHMBP2 | c.2828G>A p.R943K | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs779871930, COSV54819863, COSV54820280, COSV54825435; called by muse, mutect2, varscan2
- IPO8 | c.3017-1G>C p.X1006_splice | Splice Site (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99805685; called by muse, mutect2
- IQSEC1 | c.308C>G p.S103* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99832426; called by muse, mutect2, varscan2
- IQSEC3 | c.3044C>T p.S1015L (on ENST00000538872 / NM_001170738.2; = p.S712L on NM_015232.1) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV100407667; called by muse, mutect2, varscan2
- IRF6 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM022390, CM092335, COSV100884042, COSV65419096, COSV65419721; called by muse, mutect2, varscan2
- ISG20 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs781386863, COSV100044071; called by muse, mutect2, varscan2
- ITIH2 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100623454; called by muse, mutect2, varscan2
- ITPR1 | c.1089C>G p.D363E (on ENST00000354582; = p.D348E on NM_002222.7) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV100233359; called by muse, mutect2, varscan2
- ITPR1 | c.3446G>C p.G1149A (on ENST00000354582; = p.G1134A on NM_002222.7) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100233376; called by muse, mutect2, varscan2
- JCAD | c.1434G>C p.Q478H | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV100948597; called by muse, mutect2, varscan2
- JPH1 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286404240, COSV60614112; called by muse, mutect2, varscan2
- KATNAL1 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as rs1265045426, COSV66065176; called by muse, mutect2, varscan2
- KATNAL2 | c.842C>T p.T281I (on ENST00000356157 / NM_001353899.1; = p.T209I on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV99798304; called by muse, mutect2, varscan2
- KCNIP4 | c.114G>C p.M38I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100749759; called by muse, mutect2, varscan2
- KCNQ2 | c.2332G>T p.E778* (on ENST00000359125 / NM_172107.4; = p.E750* on NM_004518.6) | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100610604; called by muse, mutect2, varscan2
- KCNT2 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV54098601, COSV99657059; called by muse, mutect2, varscan2
- KCTD8 | c.1240C>G p.Q414E | Missense Mutation (SNP) | VAF 80/363 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV63589513, COSV63591967; called by muse, mutect2, varscan2
- KIAA1522 | c.307G>A p.E103K (on ENST00000373480 / NM_001198972.2; = p.E162K on NM_020888.3) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs1315162541, COSV99615180; called by muse, varscan2
- KIF23 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as COSV99532752; called by muse, mutect2, varscan2
- KIF27 | c.796C>G p.Q266E | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52828500, COSV99927327; called by muse, mutect2, varscan2
- KLHL38 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV100384616; called by muse, mutect2, varscan2
- KNTC1 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100063923; called by muse, varscan2
- KPNA2 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV100388898; called by muse, mutect2, varscan2
- KPRP | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV100908818; called by muse, mutect2, varscan2
- KRT2 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100548673; called by muse, mutect2, varscan2
- LAG3 | c.1494G>C p.K498N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99180021; called by muse, mutect2, varscan2
- LCMT2 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as COSV99980269; called by muse, varscan2
- LDB2 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); catalogued as COSV100455011; called by muse, mutect2, varscan2
- LDHAL6B | c.666G>C p.L222F | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.302); catalogued as rs1480105782, COSV55691415; called by muse, mutect2, varscan2
- LDHAL6B | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99896733; called by muse, mutect2, varscan2
- LIG3 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1194206854, COSV99253241; called by muse, mutect2, varscan2
- LINGO1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100796527, COSV62436071; called by mutect2, varscan2
- LRP4 | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760528582, COSV66135527; called by muse, mutect2, varscan2
- LRRC30 | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs370002253, COSV101274463; called by muse, mutect2, varscan2
- LRRC4C | c.423T>A p.N141K | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV99539941; called by muse, mutect2, varscan2
- LRRC8A | c.2147C>T p.T716M | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs985225559, COSV52185103; called by muse, mutect2, varscan2
- LRRC8C | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.392); catalogued as COSV64997219, COSV64998387; called by muse, mutect2, varscan2
- LRRTM4 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as rs951086125, COSV101299409; called by muse, mutect2, varscan2
- LRSAM1 | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773487480, COSV55940380; called by muse, mutect2, varscan2
- MANBA | c.1494G>A p.W498* (on ENST00000642252; = p.W452* on NM_005908.4) | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as COSV99899228; called by muse, mutect2, varscan2
- MAP2K1 | c.967C>G p.P323A | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1301109791, COSV100199458; called by muse, mutect2, varscan2
- MAP2K2 | c.834C>G p.I278M | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as rs766540227, COSV99502807; ClinVar: uncertain significance; called by muse, mutect2
- MAST4 | c.3665C>G p.S1222* (on ENST00000403625 / NM_001164664.2; = p.S1033* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 68/283 reads (24%) | catalogued as COSV99846070; called by muse, mutect2, varscan2
- MCM4 | c.1644G>A p.M548I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100031880; called by muse, mutect2, varscan2
- MKRN3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs781005844, COSV58808823; called by muse, mutect2, varscan2
- MS4A7 | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as COSV100279776; called by muse, mutect2, varscan2
- MSL1 | c.1143G>C p.L381F (on ENST00000398532 / NM_001365919.1; = p.L118F on NM_001012241.2) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100278227; called by muse, mutect2, varscan2
- MST1R | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV99619776; called by muse, mutect2, varscan2
- MTIF2 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV55051997, COSV55053022; called by muse, mutect2, varscan2
- MUTYH | c.1338C>G p.I446M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100588211; called by muse, mutect2, varscan2
- MXD4 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100455956, COSV61467430; called by muse, mutect2, varscan2
- MXRA8 | c.777C>G p.I259M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100492127, COSV58509941; called by muse, mutect2, varscan2
- MYBL1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV101576614, COSV101576616; called by muse, mutect2
- MYH13 | c.5497G>A p.E1833K | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99355630; called by muse, mutect2, varscan2
- MYH7 | c.5401G>T p.E1801* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as CM1410901, COSV100806734; called by muse, mutect2, varscan2
- MYO3A | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781745; called by muse, mutect2, varscan2
- MYO7A | c.2610G>C p.E870D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.98); catalogued as COSV101289280; called by muse, mutect2, varscan2
- NAMPT | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); catalogued as rs745716508, COSV99748347; called by muse, mutect2, varscan2
- NAP1L3 | c.1017C>G p.F339L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.151); catalogued as COSV100220716; called by muse, mutect2, varscan2
- NCDN | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV100357748, COSV57850664; called by muse, mutect2, varscan2
- NCF2 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV100838951; called by muse, mutect2, varscan2
- NCK1 | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99999858; called by muse, mutect2, varscan2
- NEURL2 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99510169; called by muse, mutect2
- NFATC3 | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100285793; called by muse, mutect2, varscan2
- NIBAN1 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100836647; called by muse, mutect2, varscan2
- NIPAL2 | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV100358768, COSV57838395; called by muse, mutect2, varscan2
- NKD1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.207); catalogued as COSV99194140; called by muse, mutect2, varscan2
- NLRP5 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1304132572, COSV101173364; called by muse, mutect2, varscan2
- NNT | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99239659; called by muse, mutect2, varscan2
- NOL8 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100694702; called by muse, mutect2, varscan2
- NOL8 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs1485704799, COSV62637740; called by muse, mutect2, varscan2
- NPTX1 | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV100151202, COSV60774327, COSV60776207; called by muse, mutect2, varscan2
- NPY1R | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs763046807; called by muse, mutect2, varscan2
- NR2F1 | c.1272G>C p.*424Yext*72 | Nonstop Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as COSV100504804; called by muse, mutect2
- NSFL1C | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV53792712; called by muse, mutect2
- NT5DC2 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as COSV100195528; called by muse, mutect2
- NUCB2 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100083058; called by muse, mutect2
- NUP205 | c.2703-1G>C p.X901_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99607656; called by muse, mutect2, varscan2
- OR13D1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59513392, COSV59513697, COSV59514936; called by muse, mutect2, varscan2
- OR2L3 | c.224C>G p.T75S | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV100742065; called by muse, mutect2
- OR5AP2 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV100266460, COSV57259011; called by muse, mutect2, varscan2
- OSCAR | c.165G>C p.L55F | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV99500104; called by muse, mutect2, varscan2
- OTUD5 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99332284; called by muse, mutect2, varscan2
- PAIP1 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100166765; called by muse, mutect2, varscan2
- PARM1 | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV100268649; called by muse, mutect2, varscan2
- PARP8 | c.1247G>C p.R416T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.977); catalogued as COSV55860470, COSV99892916; called by muse, mutect2, varscan2
- PCCA | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66196475; called by muse, mutect2, varscan2
- PCDH11Y | c.2057C>T p.S686F (on ENST00000400457 / NM_032973.2; = p.S675F on NM_032971.3) | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99292899; called by muse, mutect2, varscan2
- PCDH15 | c.2381G>C p.G794A | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs146468805, COSV57375394; called by muse, mutect2, varscan2
- PCDHGA10 | c.336C>G p.I112M | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV99547923; called by muse, mutect2, varscan2
- PCDHGA7 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99547922; called by muse, mutect2, varscan2
- PDCD7 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV99200166; called by muse, mutect2, varscan2
- PDZD8 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100559663; called by muse, mutect2, varscan2
- PGBD2 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 21/154 reads (14%) | catalogued as COSV61401222; called by muse, mutect2, varscan2
- PGF | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV53124428; called by mutect2, varscan2
- PHF21A | c.1061C>A p.A354E (on ENST00000418153 / NM_001101802.3; = p.A355E on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as COSV99139490; called by muse, mutect2, varscan2
- PHLDA2 | c.161C>G p.S54C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100045305; called by muse, mutect2, varscan2
- PIGZ | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as rs909823028, COSV53013775; called by muse, mutect2
- PIK3AP1 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV100226259, COSV59538435; called by muse, mutect2, varscan2
- PKM | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100065285; called by muse, mutect2, varscan2
- PLOD2 | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.097); catalogued as COSV99283363; called by muse, mutect2, varscan2
- PLXDC1 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV100195873; called by muse, mutect2, varscan2
- PNLIPRP1 | c.422G>C p.R141P | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554863726, COSV100724543, COSV62612954; called by muse, mutect2, varscan2
- PODXL2 | c.1445C>G p.S482C | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99230176; called by muse, mutect2, varscan2
- POLL | c.867C>A p.F289L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100150485; called by muse, mutect2, varscan2
- POLR1B | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as COSV99638642; called by muse, mutect2, varscan2
- POM121L12 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs761437622, COSV101374907; called by muse, mutect2, varscan2
- PRKDC | c.9585G>C p.E3195D | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100043161, COSV58061838; called by muse, mutect2, varscan2
- PRPF40B | c.1177G>A p.D393N (on ENST00000380281; = p.D387N on NM_012272.3) | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99980194; called by muse, mutect2, varscan2
- PRRT3 | c.1115C>G p.S372* | Nonsense Mutation (SNP) | VAF 64/247 reads (26%) | catalogued as COSV55977161, COSV99926768; called by muse, mutect2, varscan2
- PSME1 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99246520; called by muse, mutect2, varscan2
- PTMA | c.142G>T p.E48* (on ENST00000341369 / NM_001099285.2; = p.E47* on NM_002823.5) | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100398490; called by muse, mutect2, varscan2
- PXDNL | c.3793C>T p.Q1265* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100684428; called by muse, mutect2, varscan2
- PYCARD | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as COSV56008593, COSV99910972; called by muse, mutect2, varscan2
- RABEPK | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99413658; called by muse, mutect2
- RALGDS | c.2558C>G p.S853* | Nonsense Mutation (SNP) | VAF 86/376 reads (23%) | catalogued as COSV100924568; called by muse, mutect2, varscan2
- RASGRP2 | c.72C>T p.F24= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99377666; called by muse, mutect2
- RBM23 | c.941C>A p.S314Y (on ENST00000359890 / NM_001077351.2; = p.S298Y on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100321545; called by muse, mutect2, varscan2
- RBM28 | c.912G>C p.Q304H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1301713467, COSV99775949; called by muse, mutect2, varscan2
- RBM38 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765064896, COSV100654853; called by muse, mutect2, varscan2
- RNF31 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.229); catalogued as COSV99396317; called by muse, mutect2, varscan2
- ROBO2 | c.3358G>C p.D1120H | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100170267; called by muse, mutect2, varscan2
- ROCK1 | c.2274G>C p.L758F | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV101296634; called by muse, mutect2
- ROCK1 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1477848980, COSV101296635; called by muse, mutect2, varscan2
- RSAD2 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV65909093; called by muse, mutect2, varscan2
- RTKN | c.492G>A p.M164I (on ENST00000272430 / NM_001015055.2; = p.M151I on NM_033046.2) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV99270000; called by muse, mutect2, varscan2
- RTN4RL2 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100625488; called by muse, mutect2, varscan2
- S100Z | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.41); catalogued as rs773345066, COSV100461436; called by muse, mutect2, varscan2
- SAFB | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1442123896, COSV99413216; called by muse, mutect2, varscan2
- SAXO2 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as COSV100255936; called by muse, mutect2, varscan2
- SBF2 | c.2383G>C p.E795Q | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV99815899; called by muse, mutect2, varscan2
- SBNO1 | c.3904C>T p.R1302C (on ENST00000420886; = p.R1301C on NM_018183.5) | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs1200633056, COSV99929770; called by muse, varscan2
- SBNO1 | c.1717C>T p.Q573* (on ENST00000420886; = p.Q572* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 22/210 reads (10%) | catalogued as COSV99929774; called by muse, mutect2, varscan2
- SEC24D | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99756886; called by muse, mutect2, varscan2
- SEC31A | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100022387; called by muse, mutect2, varscan2
- SENP6 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.241); catalogued as COSV100894306; called by muse, mutect2, varscan2
- SERPINA9 | c.393G>C p.K131N | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as COSV100098865, COSV54076257; called by muse, mutect2, varscan2
- SGIP1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99390540; called by muse, mutect2, varscan2
- SH3KBP1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV101115248; called by muse, mutect2, varscan2
- SHC2 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs770600899, COSV99199231; called by muse, mutect2, varscan2
- SIGLEC8 | c.1058C>G p.S353* | Nonsense Mutation (SNP) | VAF 12/115 reads (10%) | catalogued as COSV100367416; called by muse, mutect2, varscan2
- SIK3 | c.2431C>G p.Q811E (on ENST00000445177 / NM_001366686.2; = p.Q769E on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as COSV99408892; called by muse, mutect2
- SIPA1L2 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as COSV99479829; called by muse, mutect2, varscan2
- SKP2 | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV99948327; called by muse, mutect2, varscan2
- SLC1A5 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV101314831; called by muse, mutect2
- SNTB1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101180151; called by muse, mutect2, varscan2
- SOCS5 | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100125518; called by muse, mutect2, varscan2
- SON | c.6400G>A p.E2134K | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99280021; called by muse, mutect2
- SOX7 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV100449189; called by muse, mutect2, varscan2
- SPATA5L1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748709707, COSV99973334; called by muse, mutect2, varscan2
- SPRING1 | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99732501; called by muse, mutect2, varscan2
- SPTB | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV101072434; called by muse, mutect2, varscan2
- SRPK1 | c.72G>A p.R24= | Splice Region (SNP) | VAF 68/176 reads (39%) | catalogued as COSV100644477; called by muse, mutect2, varscan2
- STRA6 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.574); catalogued as COSV100121312; called by muse, mutect2, varscan2
- STX4 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100573000; called by muse, mutect2, varscan2
- SUN2 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as rs774990510, COSV99325877; called by muse, mutect2, varscan2
- SUSD1 | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100813520; called by muse, mutect2, varscan2
- SYT1 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV54045062, COSV99697600; called by muse, mutect2, varscan2
- TATDN3 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1345803940, COSV100875284; called by muse, mutect2, varscan2
- TBC1D10A | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs767746010, COSV99304992; called by muse, varscan2
- TBC1D31 | c.2035C>A p.Q679K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99783262; called by muse, mutect2, varscan2
- TCF21 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99399781; called by muse, mutect2, varscan2
- TCHH | c.5695G>A p.G1899R | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs755708651, COSV100915521; called by muse, mutect2, varscan2
- TERF1 | c.945G>A p.L315= | Splice Region (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99401448; called by muse, mutect2, varscan2
- TF | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV99396462; called by mutect2, varscan2
- TGM2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV100821781; called by muse, mutect2, varscan2
- THEMIS2 | c.1873C>G p.L625V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100198165; called by muse, mutect2, varscan2
- TLL2 | c.1753C>G p.H585D | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100780550, COSV63573287, COSV63575956; called by muse, mutect2, varscan2
- TM9SF2 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1216051745, COSV100899784; called by muse, mutect2, varscan2
- TMEM214 | c.1940G>A p.C647Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99476554; called by muse, mutect2
- TMEM260 | c.890C>A p.S297* | Nonsense Mutation (SNP) | VAF 44/184 reads (24%) | catalogued as COSV99840724; called by muse, varscan2
- TMEM71 | c.566C>T p.S189F (on ENST00000523829 / NM_001382398.1; = p.S170F on NM_144649.3) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs1480160902, COSV100785700; called by muse, mutect2
- TMTC3 | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99898721; called by muse, mutect2, varscan2
- TNC | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs1370464694, COSV100406352; called by muse, mutect2, varscan2
- TNN | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV99513173; called by muse, mutect2
- TP63 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV99289069; called by muse, mutect2, varscan2
- TPD52 | c.244G>C p.E82Q (on ENST00000379097 / NM_001025252.3; = p.E42Q on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100990911, COSV66950145; called by muse, mutect2, varscan2
- TRAFD1 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV99987012; called by muse, mutect2, varscan2
- TRAPPC4 | c.466G>C p.V156L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100421637; called by muse, mutect2, varscan2
- TRIM28 | c.1693C>A p.P565T | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV99449490; called by muse, mutect2, varscan2
- TRIOBP | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); catalogued as COSV100731156; called by muse, mutect2, varscan2
- TRMT1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs990638321, COSV99457334; called by muse, mutect2, varscan2
- TRMT2A | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52812498, COSV99350344; called by muse, mutect2, varscan2
- TSGA10IP | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as rs780705450, COSV100408771, COSV56713512; called by muse, mutect2, varscan2
- TTC30B | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV101282815; called by muse, mutect2, varscan2
- TTN | c.77122C>G p.L25708V (on ENST00000591111; = p.L18284V on NM_003319.4) | Missense Mutation (SNP) | VAF 30/214 reads (14%) | PolyPhen probably damaging (0.996); catalogued as COSV100632417; called by muse, mutect2, varscan2
- TTN | c.27947C>T p.S9316L (on ENST00000591111; = p.S8389L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | PolyPhen possibly damaging (0.591); catalogued as COSV100632420; called by muse, mutect2, varscan2
- UBA6 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV100451941; called by muse, mutect2, varscan2
- UBE4A | c.122-1G>C p.X41_splice | Splice Site (SNP) | VAF 94/371 reads (25%) | catalogued as COSV99348636; called by muse, mutect2, varscan2
- UBR4 | c.15079G>C p.E5027Q | Missense Mutation (SNP) | VAF 107/327 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs770422497, COSV100921987; called by muse, mutect2, varscan2
- UBR4 | c.10285C>T p.H3429Y | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100921989; called by muse, mutect2, varscan2
- UFD1 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.384); catalogued as COSV99597087; called by muse, mutect2, varscan2
- UGT2A3 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV52360112; called by muse, mutect2, varscan2
- UGT2B15 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 104/395 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV100592468, COSV57732954; called by muse, mutect2, varscan2
- USO1 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs1175373143, COSV99363249; called by muse, mutect2
- USP13 | c.2165C>G p.S722C | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV55868270, COSV99831809; called by muse, mutect2, varscan2
- USP29 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.545); catalogued as COSV99518754; called by muse, mutect2, varscan2
- USP31 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99565964; called by muse, mutect2, varscan2
- USP33 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV100657227, COSV100657252; called by muse, mutect2, varscan2
- USP54 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV100161438; called by muse, mutect2, varscan2
- VPS13B | c.5635G>A p.E1879K | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV100663817; called by muse, mutect2
- VPS13B | c.9639G>C p.Q3213H | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as COSV100661966, COSV100663818, COSV62161166; called by muse, mutect2, varscan2
- VPS41 | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV100054417; called by muse, mutect2, varscan2
- VWF | c.6334C>T p.Q2112* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV54631010; called by muse, varscan2
- WDR44 | c.1110G>C p.L370F | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561997; called by muse, mutect2, varscan2
- WDR70 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 36/155 reads (23%) | catalogued as COSV99460595, COSV99460801; called by muse, mutect2, varscan2
- WDR90 | c.2076C>G p.Y692* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99554250; called by muse, mutect2, varscan2
- XIRP1 | c.4866G>C p.Q1622H | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1414927635, COSV100454006; called by muse, mutect2, varscan2
- XPOT | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV100225773; called by muse, mutect2, varscan2
- YTHDF1 | c.28-1G>C p.X10_splice | Splice Site (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100945881; called by muse, mutect2, varscan2
- YWHAZ | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.5); catalogued as COSV62053827; called by muse, mutect2, varscan2
- ZAN | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV100770474; called by muse, mutect2, varscan2
- ZBTB7B | c.1113G>C p.E371D (on ENST00000292176; = p.E405D on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99421606; called by muse, mutect2, varscan2
- ZC3H8 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748316181, COSV99735702; called by muse, mutect2, varscan2
- ZCCHC8 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.812); catalogued as COSV100288881; called by muse, mutect2, varscan2
- ZFP2 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV63725277, COSV63727016; called by muse, mutect2, varscan2
- ZFP2 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 26/109 reads (24%) | catalogued as COSV100797135; called by muse, mutect2, varscan2
- ZGRF1 | c.5554G>A p.E1852K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV101500547, COSV101500683; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1626G>C p.Q542H | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV56272371, COSV56272966; called by muse, mutect2, varscan2
- ZNF350 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV99702733; called by muse, mutect2, varscan2
- ZNF484 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV100214912; called by muse, mutect2, varscan2
- ZNF486 | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV100631344, COSV100631512; called by muse, mutect2, varscan2
- ZNF514 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV99728040; called by muse, mutect2, varscan2
- ZNF514 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99727907, COSV99728042; called by muse, mutect2, varscan2
- ZNF521 | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as COSV100833508; called by muse, mutect2, varscan2
- ZNF615 | c.433A>T p.N145Y | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.367); catalogued as COSV100944005; called by muse, mutect2
- ZNF623 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.234); catalogued as COSV71697219; called by muse, mutect2, varscan2
- ZNF625 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV100503183; called by muse, mutect2, varscan2
- ZNF629 | c.2250G>T p.K750N | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV99355056; called by muse, mutect2, varscan2
- ZNF764 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99411232; called by muse, mutect2, varscan2
- ZNF80 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs764278880, COSV100352166, COSV57360801, COSV57362004; called by muse, mutect2
- ZSCAN29 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101212253; called by muse, mutect2, varscan2
- ZSCAN30 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100310386; called by muse, mutect2, varscan2
- COL25A1 | c.1273_1276dup p.T426Sfs*3 | Frame Shift Ins (INS) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- FCGBP | c.8876G>A p.G2959D | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- H2AC21 | c.378_*2del | Nonstop Mutation (DEL) | VAF 12/118 reads (10%) | called by mutect2, pindel
- PDZK1 | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); called by mutect2, varscan2
- TRAV3 | c.45G>A p.L15= | Splice Region (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- ABCA10 | c.3846C>T p.F1282= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as COSV52232200; called by muse, mutect2, varscan2
- ABCB4 | c.1269G>A p.Q423= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs762940965, COSV99711390; called by muse, mutect2, varscan2
- ABCC4 | c.948C>T p.L316= | Silent (SNP) | VAF 48/297 reads (16%) | catalogued as COSV100972830; called by muse, mutect2, varscan2
- ACACB | c.2370C>T p.C790= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as rs1406084359, COSV100623326; called by muse, mutect2
- ADA | c.750C>T p.N250= | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as COSV100596158; called by muse, mutect2, varscan2
- ADGRF1 | c.1515G>C p.V505= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV99347668; called by muse, varscan2
- ADGRF1 | c.1236C>T p.S412= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs1308078840, COSV99347679; called by muse, mutect2, varscan2
- ALS2 | c.828C>T p.L276= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs748243739, COSV51889498, COSV99970116; called by muse, mutect2, varscan2
- APBB2 | c.321C>T p.L107= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV55963778; called by muse, mutect2, varscan2
- APOLD1 | c.492G>A p.E164= (on ENST00000326765 / NM_001130415.2; = p.E133= on NM_030817.3) | Silent (SNP) | VAF 46/153 reads (30%) | catalogued as rs1376467433, COSV100458907; called by muse, mutect2, varscan2
- ATAD2B | c.3636C>T p.I1212= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as rs773458827, COSV99478538; called by muse, mutect2, varscan2
- ATAD5 | c.4869G>A p.K1623= | Silent (SNP) | VAF 62/171 reads (36%) | catalogued as COSV100430263; called by muse, mutect2, varscan2
- ATP2B2 | c.2163C>T p.G721= (on ENST00000352432; = p.G687= on NM_001683.5) | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as rs758683952, COSV59492411; called by muse, mutect2, varscan2
- BPIFB3 | c.351G>A p.L117= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100972434; called by muse, mutect2, varscan2
- BRD2 | c.114C>T p.L38= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV100875850; called by muse, mutect2, varscan2
- BSN | c.5487C>G p.L1829= | Silent (SNP) | VAF 8/121 reads (7%) | catalogued as COSV99609949; called by muse, mutect2
- BTBD10 | c.984G>A p.Q328= | Silent (SNP) | VAF 51/216 reads (24%) | catalogued as COSV99533950; called by muse, mutect2, varscan2
- BTD | c.889C>T p.L297= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as COSV100329869; called by muse, mutect2, varscan2
- C1GALT1C1L | c.573G>A p.L191= | Silent (SNP) | VAF 59/242 reads (24%) | called by muse, mutect2, varscan2
- C1orf141 | c.942C>G p.L314= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as rs1205722387, COSV63993620; called by muse, mutect2, varscan2
- CAMSAP2 | c.903G>A p.L301= (on ENST00000236925 / NM_001297707.2; = p.L290= on NM_203459.3) | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV99374425; called by muse, mutect2, varscan2
- CATIP | c.303C>T p.C101= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs150544491; called by muse, mutect2, varscan2
- CATSPERG | c.2304C>T p.F768= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV53048707, COSV99286968; called by muse, mutect2, varscan2
- CCNB3 | c.4026G>A p.L1342= | Silent (SNP) | VAF 76/127 reads (60%) | catalogued as COSV99329507; called by muse, mutect2, varscan2
- CD300A | c.330C>T p.L110= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as COSV100178003; called by muse, mutect2, varscan2
- CDKL5 | c.2655G>A p.G885= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV101184497; called by muse, mutect2, varscan2
- CES2 | c.1065G>A p.R355= | Silent (SNP) | VAF 66/274 reads (24%) | catalogued as COSV100399440; called by muse, mutect2, varscan2
- CFAP58 | c.1482G>C p.V494= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as COSV100866192; called by muse, mutect2, varscan2
- COL6A6 | c.3786G>C p.L1262= | Silent (SNP) | VAF 65/242 reads (27%) | catalogued as COSV100651002; called by muse, mutect2, varscan2
- COL7A1 | c.2688C>T p.F896= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100097821; called by muse, mutect2, varscan2
- COL7A1 | c.2355C>T p.L785= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV100096302; called by muse, varscan2
- CRTAC1 | c.1431C>T p.I477= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs375834437, COSV100085230; called by muse, mutect2, varscan2
- CRTAP | c.132C>T p.L44= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs114946269, COSV100310215; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSGALNACT1 | c.876G>A p.G292= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100175684; called by muse, mutect2, varscan2
- CTSD | c.1128G>A p.P376= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs929763593, COSV52589592; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCTN2 | c.1191G>A p.K397= (on ENST00000548249 / NM_001261413.2; = p.K402= on NM_006400.4) | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as rs1169823594, COSV100851837; called by muse, mutect2
- DEF6 | c.687G>A p.L229= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100359562; called by muse, mutect2
- DHX8 | c.3423C>T p.L1141= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99292667; called by muse, mutect2, varscan2
- DIPK2A | c.258C>G p.L86= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100237477; called by muse, mutect2, varscan2
- DNAH8 | c.3096G>C p.L1032= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100547309; called by muse, mutect2, varscan2
- DOCK1 | c.4221G>A p.V1407= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV99733039; called by muse, mutect2, varscan2
- DOCK6 | c.1215G>A p.V405= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99371124; called by muse, mutect2, varscan2
- DRC3 | c.816C>A p.L272= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1414994135, COSV58263259; called by muse, varscan2
- DRC7 | c.2100G>A p.L700= | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as COSV61053668; called by muse, mutect2, varscan2
- DSCAM | c.1953G>C p.T651= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs1460447638, COSV101261627; called by muse, mutect2, varscan2
- DUOXA1 | c.84C>T p.I28= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV99973591; called by muse, mutect2, varscan2
- DYNC2H1 | c.5763G>C p.L1921= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100519885; called by muse, mutect2
- EFEMP2 | c.1134C>A p.I378= | Silent (SNP) | VAF 35/174 reads (20%) | catalogued as COSV100337413; called by muse, mutect2, varscan2
- EFNB1 | c.135G>A p.L45= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV99214999; called by muse, mutect2, varscan2
- EHD2 | c.762C>T p.I254= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs775008579, COSV54407448; called by muse, mutect2, varscan2
- EPPK1 | c.5991C>T p.L1997= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs782373505, COSV101599969; called by muse, mutect2, varscan2
- FAM118B | c.186C>G p.L62= | Silent (SNP) | VAF 84/382 reads (22%) | catalogued as COSV100796935; called by muse, mutect2, varscan2
- FAT4 | c.4368C>A p.S1456= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as rs997026775, COSV101272019, COSV101272898; called by muse, mutect2, varscan2
- FLT1 | c.1356G>T p.L452= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV99167675; called by muse, mutect2, varscan2
- GABRR3 | c.981C>G p.L327= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as COSV72084469; called by muse, mutect2
- GALR2 | c.189C>T p.F63= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100203697; called by muse, mutect2, varscan2
- GALR2 | c.312C>T p.L104= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100203383, COSV100203698; called by muse, mutect2, varscan2
- GJB6 | c.372G>A p.Q124= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99576186; called by muse, mutect2, varscan2
- GPR137 | c.135C>G p.L45= | Silent (SNP) | VAF 49/201 reads (24%) | catalogued as COSV100464548; called by muse, mutect2, varscan2
- GSK3A | c.996C>T p.I332= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99725480; called by muse, mutect2, varscan2
- H1-0 | c.537G>A p.V179= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99959959; called by muse, mutect2, varscan2
- HECTD4 | c.2835C>T p.L945= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100295771, COSV100296233; called by muse, mutect2, varscan2
- IGSF10 | c.6426G>A p.R2142= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV99196489; called by muse, mutect2, varscan2
- KAT6B | c.4659C>T p.S1553= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs147158118; called by muse, mutect2, varscan2
- KCTD13 | c.291C>G p.L97= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100442319; called by muse, mutect2, varscan2
- KDM3B | c.3615G>A p.L1205= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV58690667, COSV58691369; called by muse, mutect2, varscan2
- KIF24 | c.1003C>T p.L335= | Silent (SNP) | VAF 61/115 reads (53%) | catalogued as COSV100799384; called by muse, mutect2, varscan2
- KLHL3 | c.1566C>T p.D522= | Silent (SNP) | VAF 32/248 reads (13%) | catalogued as rs768057381, COSV100553603; called by muse, mutect2, varscan2
- KLHL3 | c.372C>T p.L124= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs757282320, COSV100553605; called by muse, mutect2, varscan2
- LMX1A | c.222C>T p.F74= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs1352117885, COSV54216496, COSV54220663; called by muse, mutect2, varscan2
- LNX1 | c.858C>G p.L286= (on ENST00000263925 / NM_001126328.3; = p.L190= on NM_032622.2) | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV55785057; called by muse, mutect2, varscan2
- LPO | c.1395C>G p.R465= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as COSV99229464; called by muse, mutect2, varscan2
- LRP2 | c.2394C>A p.L798= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV99790441; called by muse, mutect2, varscan2
- LRRC7 | c.3660G>C p.V1220= (on ENST00000651989 / NM_001370785.2; = p.V1187= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV50439033, COSV99230087; called by muse, mutect2, varscan2
- MAP2K3 | c.741C>T p.V247= (on ENST00000342679 / NM_145109.3; = p.V218= on NM_002756.4) | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as rs1291901281, COSV100384605, COSV57578973; called by muse, mutect2, varscan2
- MEGF6 | c.1197C>T p.A399= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs374339674; called by muse, mutect2, varscan2
- MICAL2 | c.2379C>G p.L793= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99818443; called by muse, mutect2, varscan2
- MICALL2 | c.1845G>A p.P615= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as rs778253235, COSV99876306; called by muse, mutect2, varscan2
- MITF | c.1482C>T p.S494= (on ENST00000448226 / NM_006722.3; = p.S394= on NM_000248.4) | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100097205, COSV100097489; called by muse, mutect2, varscan2
- MST1R | c.1359G>A p.V453= | Silent (SNP) | VAF 47/151 reads (31%) | catalogued as COSV99619778; called by muse, mutect2, varscan2
- MYH14 | c.558G>T p.L186= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99224284; called by muse, mutect2, varscan2
- NET1 | c.627C>T p.I209= (on ENST00000355029 / NM_001047160.3; = p.I155= on NM_005863.5) | Silent (SNP) | VAF 61/255 reads (24%) | catalogued as COSV100742391; called by muse, mutect2, varscan2
- NTRK2 | c.1557C>T p.I519= (on ENST00000323115 / NM_001369534.1; = p.I535= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV99458871; called by muse, mutect2, varscan2
- NUDC | c.939G>A p.L313= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV100264669; called by muse, mutect2
- OR13C3 | c.750C>T p.F250= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV66166240, COSV66166263; called by muse, mutect2, varscan2
- OR5A1 | c.546C>T p.C182= | Silent (SNP) | VAF 79/353 reads (22%) | catalogued as rs1032680539, COSV100118347, COSV57375591; called by muse, mutect2, varscan2
- PAH | c.699C>T p.F233= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as CM010963, CM159600, COSV100188471; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.885C>G p.L295= (on ENST00000259318 / NM_001136562.3; = p.L526= on NM_007203.5) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99395823; called by muse, mutect2, varscan2
- PCARE | c.2226G>A p.E742= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV100527922; called by muse, mutect2, varscan2
- PCLO | c.6765T>G p.G2255= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100437167, COSV100438430; called by muse, mutect2, varscan2
- PDE2A | c.2235C>A p.I745= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100558448; called by muse, mutect2, varscan2
- PDZD2 | c.7455G>C p.L2485= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV56854914; called by muse, mutect2, varscan2
- PHRF1 | c.1266G>A p.L422= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as COSV52765232; called by muse, mutect2, varscan2
- PLEKHM1 | c.2895C>T p.L965= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV69599075; called by muse, mutect2, varscan2
- POLR3H | c.585G>A p.L195= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs746361616, COSV99347805; called by muse, mutect2, varscan2
- PRORP | c.663C>T p.I221= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs1566438655, COSV99156607; called by muse, mutect2, varscan2
- PTDSS2 | c.393G>C p.V131= | Silent (SNP) | VAF 68/337 reads (20%) | catalogued as COSV100339326, COSV57277681; called by muse, mutect2, varscan2
- PUS7 | c.411C>T p.F137= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs753851280, COSV100708657; called by muse, mutect2
- RAB11FIP5 | c.1656G>A p.L552= | Silent (SNP) | VAF 30/329 reads (9%) | catalogued as COSV99242491; called by muse, mutect2
- RAP2A | c.87C>T p.I29= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV55354229; called by muse, varscan2
- RBM12B | c.2313C>T p.F771= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV101234565; called by muse, mutect2, varscan2
- REXO1 | c.2943C>T p.L981= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs774661515, COSV99402681; called by mutect2, varscan2
- RFX5 | c.252G>T p.L84= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99303343, COSV99303384; called by muse, mutect2, varscan2
- RHBDF2 | c.486G>A p.L162= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV100489699; called by muse, mutect2, varscan2
- RHOQ | c.30C>T p.L10= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs753794189, COSV99475984; called by muse, mutect2
- RNF43 | c.471G>A p.L157= | Silent (SNP) | VAF 21/229 reads (9%) | catalogued as COSV101348565; called by muse, mutect2
- SEPTIN9 | c.462C>T p.I154= (on ENST00000427177 / NM_001113491.2; = p.I136= on NM_006640.4) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs747374352, COSV100218811; called by muse, varscan2
- SLC27A6 | c.1515C>T p.F505= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV99323568; called by muse, mutect2, varscan2
- SLC36A2 | c.288C>T p.F96= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as rs749069005, COSV58862106; called by muse, mutect2, varscan2
- SLIT3 | c.2916G>C p.L972= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV100270239; called by muse, mutect2, varscan2
- SPATA6L | c.1026G>A p.K342= (on ENST00000461761 / NM_001353484.2; = p.K284= on NM_001039395.4 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV101121933; called by muse, mutect2, varscan2
- SPDYA | c.582C>T p.I194= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100478246; called by muse, mutect2, varscan2
- SPOCK1 | c.516C>T p.L172= | Silent (SNP) | VAF 57/242 reads (24%) | catalogued as rs374427870; called by muse, mutect2, varscan2
- SPTBN2 | c.3150C>T p.L1050= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100020592; called by muse, mutect2, varscan2
- SPX | c.177G>C p.R59= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV57021923; called by muse, mutect2
- ST3GAL6 | c.942C>G p.L314= | Silent (SNP) | VAF 39/161 reads (24%) | catalogued as COSV54580576, COSV99505321; called by muse, mutect2, varscan2
- STK38 | c.711G>A p.L237= | Silent (SNP) | VAF 101/296 reads (34%) | catalogued as COSV100007554; called by muse, mutect2, varscan2
- TBC1D24 | c.882C>T p.L294= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99565315; called by muse, mutect2, varscan2
- TBL1X | c.1539C>T p.F513= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV99483223; called by muse, mutect2, varscan2
- TMEM202 | c.228A>G p.P76= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100499280; called by muse, mutect2, varscan2
- TP63 | c.1056G>A p.R352= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV53206464, COSV99289078; called by muse, mutect2, varscan2
- TPM3 | c.624G>C p.L208= (on ENST00000368530 / NM_001364682.1; = p.L171= on NM_153649.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/426 reads (12%) | catalogued as COSV99666697; called by muse, mutect2, varscan2
- TPRKB | c.192C>G p.L64= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV55540980; called by muse, mutect2, varscan2
- TRAPPC2L | c.153C>A p.V51= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99242799, COSV99243492; called by muse, mutect2, varscan2
- TRERF1 | c.1974G>A p.P658= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs776967139, COSV100551830; called by muse, mutect2, varscan2
- TRGC2 | c.267C>T p.I89= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as rs779391467; called by muse, varscan2
- TTLL11 | c.861G>A p.L287= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as COSV100389390; called by muse, mutect2, varscan2
- TUBB2B | c.738G>A p.L246= | Silent (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- USP50 | c.819C>T p.F273= (on ENST00000616326; = p.F264= on NM_203494.5) | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs750548492, COSV101597738; called by muse, mutect2, varscan2
- VHL | c.354C>T p.L118= | Silent (SNP) | VAF 62/225 reads (28%) | catalogued as rs1051892430, COSV56560146, COSV56562224; called by muse, mutect2, varscan2
- WDCP | c.1866C>T p.L622= | Silent (SNP) | VAF 51/215 reads (24%) | catalogued as COSV99722250; called by muse, mutect2, varscan2
- WDR77 | c.348C>T p.V116= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV99330996; called by muse, mutect2, varscan2
- XDH | c.1590G>A p.E530= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV101052490, COSV65147962; called by muse, mutect2, varscan2
- YIPF3 | c.639C>T p.I213= | Silent (SNP) | VAF 56/217 reads (26%) | catalogued as COSV100397155; called by muse, mutect2, varscan2
- YY1AP1 | c.2280G>A p.P760= (on ENST00000295566 / NM_139118.2; = p.P703= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs777065440, COSV99804801; called by muse, mutect2, varscan2
- ZCCHC8 | c.1338C>T p.L446= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs746324794, COSV60318104; called by muse, mutect2, varscan2
- ZFHX4 | c.1581G>A p.A527= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99268282; called by muse, mutect2, varscan2
- ZFP1 | c.747C>T p.F249= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs1219930558, COSV100182166; called by muse, mutect2, varscan2
- ZNF16 | c.1038G>A p.E346= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs764790338, COSV99429940; called by muse, mutect2, varscan2
- ZNF425 | c.1020C>T p.R340= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs750814428, COSV100955624; called by muse, mutect2, varscan2
- AC024940.1 | n.3402C>T | RNA (SNP) | VAF 36/197 reads (18%) | catalogued as rs763410316; called by muse, mutect2, varscan2
- ATAD3B | c.325-55C>T | Intron (SNP) | VAF 21/44 reads (48%) | catalogued as rs757834254, COSV100426649; called by muse, mutect2, varscan2
- ATP6AP1L | n.1874C>T | RNA (SNP) | VAF 18/90 reads (20%) | catalogued as rs201337750, COSV66475306; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.-2G>A | 5'UTR (SNP) | VAF 9/30 reads (30%) | catalogued as rs1202051026, COSV99141665; called by muse, mutect2, varscan2
- MIR520G | n.88G>A | RNA (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- NDUFA3 | c.*139C>G | 3'UTR (SNP) | VAF 14/45 reads (31%) | catalogued as rs1443384911, COSV100338310; called by muse, mutect2, varscan2
- NTRK3 | c.1890-1772G>C | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- PAXIP1 | c.325-2807G>A | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2, varscan2
- PKD1L2 | n.1174C>T | RNA (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2
- RPL15 | c.-1G>A | 5'UTR (SNP) | VAF 27/111 reads (24%) | catalogued as COSV100323292; called by muse, mutect2, varscan2
- TTN | c.10361-4583C>T | Intron (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100632424; called by muse, mutect2, varscan2
- TUBB7P | n.1288G>A | RNA (SNP) | VAF 98/343 reads (29%) | catalogued as rs370967028; called by muse, mutect2
